Somatic mutation profile of tumor specimen f2a13f8d-b129-4567-beae-049b15 (aliquot f2a13f8d-b129-4567-beae-049b15_D6_2) from CPTAC case 11CO051, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen f2a13f8d-b129-4567-beae-049b15: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a71d125b-cdd2-4430-a62c-b62efabbccb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 07245471-6673-4b5c-a88e-ee5904 (Blood Derived Normal), aliquot 07245471-6673-4b5c-a88e-ee5904_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d259926-0fa8-4cb9-95eb-c232c08935d3

The open-access MAF lists 1,152 somatic variants for this specimen: 764 protein-altering or splice-affecting, 243 silent, 145 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 553, Silent 243, Frame Shift Del 129, Intron 72, Nonsense Mutation 36, 3'UTR 23, Frame Shift Ins 18, 5'UTR 16, 5'Flank 15, RNA 13, Splice Site 11, Splice Region 11.

Variants (750 of 1,152; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CEL | c.1785del p.V596Cfs*111 (on ENST00000673714; = p.V593Cfs*111 on NM_001807.6) | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | catalogued as rs193922638; ClinVar: likely pathogenic; called by mutect2, varscan2
- CFAP300 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as rs561237622; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAAF4 | c.523del p.I175Ffs*21 | Frame Shift Del (DEL) | VAF 36/98 reads (37%) | catalogued as rs751610886; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- EP300 | c.4397G>T p.W1466L | Missense Mutation (SNP) | VAF 36/211 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV54329712, COSV54343301, COSV54343868; called by muse, mutect2, varscan2
- GRIN2B | c.99dup p.S34Qfs*25 | Frame Shift Ins (INS) | VAF 52/382 reads (14%) | catalogued as rs398122823; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MFRP | chr11:119345562 ins G | 5'Flank (INS) | VAF 38/314 reads (12%) | catalogued as rs587776596; ClinVar: pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 50/154 reads (32%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- OCA2 | c.2360C>T p.A787V | Missense Mutation (SNP) | VAF 62/180 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200457227, CM981408, COSV62337810; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 6/49 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- PRSS56 | c.1066del p.Q356Rfs*148 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | catalogued as rs730882064; ClinVar: pathogenic; called by mutect2, varscan2
- ABCB5 | c.1600G>A p.A534T (on ENST00000404938 / NM_001163941.2; = p.A89T on NM_178559.6) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as rs745873483, COSV51704716; called by muse, mutect2, varscan2
- ABCB8 | c.1531G>A p.G511R (on ENST00000297504 / NM_001282291.2; = p.G494R on NM_007188.5) | Missense Mutation (SNP) | VAF 64/302 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs532957161; called by muse, mutect2, varscan2
- AC242842.3 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 85/406 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs1249153636; called by muse, mutect2, varscan2
- ACACB | c.4597G>A p.V1533M | Missense Mutation (SNP) | VAF 63/369 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as rs1171171145; called by muse, mutect2, varscan2
- ACAP3 | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 84/374 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs757717274, COSV61222058; called by muse, mutect2, varscan2
- ACSS1 | c.860A>G p.D287G | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60221831; called by muse, mutect2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 31/77 reads (40%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS8 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs776541266; called by muse, mutect2, varscan2
- ADAMTSL2 | c.799G>A p.G267S | Missense Mutation (SNP) | VAF 73/372 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779112036, CM166984, COSV63203794; called by muse, mutect2
- ADGRG4 | c.8597C>T p.A2866V | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV54953138; called by muse, mutect2, varscan2
- ADGRG6 | c.2867A>G p.Y956C | Missense Mutation (SNP) | VAF 62/271 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1303109223, COSV51593598; called by muse, mutect2, varscan2
- AHDC1 | c.350A>G p.N117S | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV99899345; called by muse, mutect2, varscan2
- AHNAK | c.15193G>A p.A5065T | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs1393268352; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 24/130 reads (18%) | catalogued as COSV62339755; called by mutect2, varscan2
- ALDH1L1 | c.2233G>A p.D745N | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs763483275, COSV56412618; called by muse, mutect2, varscan2
- ALDOB | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 122/546 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201397971, COSV66397796; ClinVar: uncertain significance; called by mutect2, varscan2
- ANK3 | c.12420del p.K4140Nfs*15 (on ENST00000280772 / NM_001320874.2; = p.K661Nfs*15 on NM_001149.3) | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | catalogued as rs1466658148; called by mutect2, pindel, varscan2
- ANKRD31 | c.1533del p.G512Vfs*20 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | catalogued as rs1279723268; called by mutect2, pindel
- ANKRD35 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as rs782683294, COSV100841857; called by muse, mutect2
- ANKRD7 | c.174del p.K58Nfs*8 | Frame Shift Del (DEL) | VAF 24/150 reads (16%) | catalogued as rs759672590, COSV99500935; called by mutect2, pindel, varscan2
- APC | c.3103C>T p.Q1035* | Nonsense Mutation (SNP) | VAF 80/366 reads (22%) | catalogued as CM106362, COSV57349980; called by muse, mutect2, varscan2
- APOBR | c.1681G>A p.A561T (on ENST00000431282; = p.A570T on NM_018690.4) | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs538679050; called by muse, mutect2, varscan2
- APPL1 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs746445160; called by muse, mutect2, varscan2
- APPL1 | c.1695G>A p.T565= | Splice Region (SNP) | VAF 27/150 reads (18%) | catalogued as rs780307990; called by muse, mutect2, varscan2
- ARAP1 | c.2636C>T p.A879V (on ENST00000393609 / NM_001040118.2; = p.A634V on NM_015242.4) | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as COSV61989478; called by muse, mutect2, varscan2
- ARHGAP4 | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1557102969; called by muse, mutect2, varscan2
- ARHGDIA | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs929782154; called by muse, mutect2
- ARHGEF1 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868960086, COSV61526025; called by muse, mutect2
- ARHGEF10L | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs187517339; called by muse, mutect2, varscan2
- ASAP3 | c.1432A>G p.M478V | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs753097379; called by muse, mutect2, varscan2
- ATP7A | c.1510G>T p.A504S | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.559); catalogued as COSV58451154; called by muse, mutect2, varscan2
- AVPR1A | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 28/710 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54547072; called by muse, mutect2
- AXIN1 | c.308G>T p.R103M | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51994201; called by muse, mutect2, varscan2
- B4GALNT3 | c.2645T>C p.I882T | Missense Mutation (SNP) | VAF 46/259 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1565613000; called by muse, mutect2, varscan2
- BAAT | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as rs754845084; called by muse, mutect2, varscan2
- BBX | c.2671C>T p.P891S (on ENST00000325805 / NM_001142568.3; = p.P861S on NM_020235.7) | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV57895651; called by muse, mutect2
- BCKDK | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.014); catalogued as rs575078725; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 73/146 reads (50%) | catalogued as rs772920507, COSV65808737; called by mutect2, varscan2
- BMT2 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV51774965; called by muse, mutect2, varscan2
- BNC2 | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 81/463 reads (17%) | catalogued as rs1296819700, COSV101033244; called by muse, mutect2, varscan2
- BPTF | c.6826G>T p.A2276S | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV58847245; called by muse, mutect2
- BRCA2 | c.9538C>T p.L3180F | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200598289, CM1210132, COSV101200942; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 23/100 reads (23%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BSN | c.10829G>A p.R3610Q | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs1371788564; called by muse, mutect2, varscan2
- BTBD7 | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 8/110 reads (7%) | catalogued as rs1017916547, COSV100597990, COSV58285585; called by muse, mutect2
- C12orf42 | c.1009del p.R337Afs*19 | Frame Shift Del (DEL) | VAF 90/287 reads (31%) | catalogued as rs771322722; called by mutect2, pindel, varscan2
- C14orf119 | c.164A>G p.E55G | Missense Mutation (SNP) | VAF 97/411 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.898); catalogued as rs781233103; called by muse, mutect2, varscan2
- C17orf67 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 23/97 reads (24%) | catalogued as rs775112986; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C1orf189 | c.34_35del p.S12Ffs*8 | Frame Shift Del (DEL) | VAF 15/90 reads (17%) | catalogued as rs755305410; called by pindel, varscan2
- C4orf54 | c.4488del p.N1497Tfs*13 | Frame Shift Del (DEL) | VAF 45/381 reads (12%) | catalogued as rs1249107798; called by mutect2, pindel, varscan2
- C9orf135 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs368133993; called by muse, mutect2
- CACNA1C | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.335); catalogued as rs1064796583, COSV59705496; ClinVar: uncertain significance; called by muse, mutect2
- CACTIN | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50267185; called by muse, mutect2, varscan2
- CAMTA1 | c.4190T>C p.M1397T | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57886029; called by muse, mutect2, varscan2
- CARD14 | c.123del p.Y42Tfs*36 | Frame Shift Del (DEL) | VAF 31/177 reads (18%) | catalogued as rs1332544672; called by mutect2, pindel, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 12/92 reads (13%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC7 | c.3347A>G p.H1116R | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.984); catalogued as COSV56552521; called by muse, mutect2, varscan2
- CCDC88A | c.3603-3del | Splice Region (DEL) | VAF 12/47 reads (26%) | catalogued as rs768846308; called by mutect2, pindel, varscan2
- CCND3 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs142862109, COSV57828402; called by muse, mutect2, varscan2
- CD8A | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 57/412 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.401); catalogued as COSV99374619; called by muse, mutect2, varscan2
- CDK13 | c.3752G>A p.R1251Q | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.096); catalogued as rs1179237555; called by muse, mutect2, varscan2
- CDK5 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52521055; called by muse, mutect2, varscan2
- CELSR1 | c.2576C>T p.T859M | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs375675019; called by muse, mutect2, varscan2
- CEP295 | c.2806C>T p.R936C | Missense Mutation (SNP) | VAF 51/226 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.436); catalogued as rs1025872449, COSV100292294; called by muse, mutect2, varscan2
- CFH | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.925); catalogued as rs1160820929, COSV62776174; called by muse, mutect2
- CHD6 | c.7304G>A p.R2435Q | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs747738727; called by muse, varscan2
- CHMP4C | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs528902989, COSV51927708; called by muse, varscan2
- CIITA | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 83/350 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs199476070; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- CKMT2 | c.499A>G p.T167A | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as rs767330429; called by muse, mutect2, varscan2
- CLIP2 | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782141623, COSV56286157; called by muse, mutect2, varscan2
- CLTC | c.1643A>G p.Q548R | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.968); catalogued as COSV99293055; called by muse, mutect2, varscan2
- CMTM5 | c.553G>A p.G185R (on ENST00000339180 / NM_001288746.2; = p.G118R on NM_138460.3) | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.998); catalogued as rs752085751, COSV100197922; called by muse, mutect2, varscan2
- CNGA1 | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 60/296 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs756398915, COSV62054293; called by muse, mutect2, varscan2
- CNRIP1 | c.269A>G p.D90G | Missense Mutation (SNP) | VAF 74/359 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); catalogued as COSV55148262; called by muse, mutect2, varscan2
- COL22A1 | c.4393C>T p.R1465C | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs758413253, COSV57334771; called by muse, mutect2
- COMMD5 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 119/501 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1420187633, COSV100295984; called by muse, mutect2, varscan2
- CTBP2 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 65/323 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.244); catalogued as COSV58333245, COSV58335458; called by muse, mutect2, varscan2
- CTNND2 | c.1367G>A p.S456N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV58908549; called by muse, mutect2, varscan2
- CWF19L1 | c.821C>A p.S274Y | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV62499221; called by muse, mutect2, varscan2
- CYLC1 | c.1036G>T p.D346Y | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV61411507, COSV61416363; called by muse, mutect2, varscan2
- CYP11B1 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 66/373 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as rs1304494959, COSV52825464, COSV52828663; called by muse, mutect2, varscan2
- DACH1 | c.1174T>A p.S392T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.003); catalogued as COSV57492903; called by muse, mutect2, varscan2
- DCAF8L2 | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.063); catalogued as rs756619299; called by muse, mutect2, varscan2
- DCLK1 | c.1589A>C p.K530T | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55189569, COSV55200088; called by muse, mutect2, varscan2
- DCT | c.555del p.F185Lfs*14 | Frame Shift Del (DEL) | VAF 28/162 reads (17%) | catalogued as rs762895555; called by mutect2, varscan2
- DCX | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 76/320 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1230386660, COSV57572451; called by muse, mutect2, varscan2
- DDR1 | c.1696G>A p.V566I (on ENST00000324771; = p.V529I on NM_001954.4) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as rs370113205; called by muse, mutect2, varscan2
- DEF8 | c.398G>A p.R133H (on ENST00000268676 / NM_207514.3; = p.R72H on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.14); catalogued as rs746724442; called by muse, mutect2, varscan2
- DES | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1406795636; called by muse, mutect2, varscan2
- DHRS9 | c.669del p.K223Nfs*25 | Frame Shift Del (DEL) | VAF 22/112 reads (20%) | catalogued as rs756920263; called by mutect2, varscan2
- DIP2B | c.4066G>A p.A1356T | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV56583374, COSV56583491; called by muse, mutect2
- DISP3 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1186903277, COSV53819377; called by muse, mutect2, varscan2
- DLGAP3 | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 54/243 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99332043; called by muse, mutect2, varscan2
- DLX6 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV104375421; called by muse, mutect2, varscan2
- DNAH10 | c.5623A>T p.I1875F (on ENST00000409039; = p.I1814F on NM_207437.3) | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV68993980; called by muse, mutect2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as rs751671358; called by mutect2, varscan2
- DNER | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 30/178 reads (17%) | catalogued as rs754284770, COSV59166052; called by muse, mutect2, varscan2
- DNHD1 | c.13294G>A p.A4432T | Missense Mutation (SNP) | VAF 99/693 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as rs1302452922, COSV54431692; called by muse, mutect2, varscan2
- DNPH1 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs551858852; called by muse, mutect2, varscan2
- DOCK2 | c.657del p.T220Pfs*8 | Frame Shift Del (DEL) | VAF 24/106 reads (23%) | catalogued as COSV56971078; called by mutect2, pindel, varscan2
- DOCK2 | c.5294C>T p.A1765V | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs141274816; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSTN | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1184752989, COSV55712556; called by muse, mutect2, varscan2
- DUOX2 | c.4474C>T p.R1492C | Missense Mutation (SNP) | VAF 148/390 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747720952, CM159748, COSV66530615; called by muse, mutect2, varscan2
- DYNC2H1 | c.4260G>A p.E1420= | Splice Region (SNP) | VAF 8/119 reads (7%) | catalogued as rs1295844795; called by muse, mutect2
- EIF2AK3 | c.3278G>A p.R1093H | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765878566, COSV57545739; called by muse, mutect2, varscan2
- EIF4A3 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs200525685, COSV53920713; called by muse, mutect2, varscan2
- EIF4G2 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1440253077, COSV60596994; called by muse, mutect2, varscan2
- EMG1 | c.727dup p.V243Gfs*26 | Frame Shift Ins (INS) | VAF 25/137 reads (18%) | catalogued as rs782102656; called by mutect2, pindel, varscan2
- EPAS1 | c.790C>G p.L264V | Missense Mutation (SNP) | VAF 102/411 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199738228; called by muse, mutect2, varscan2
- ERICH3 | c.2296dup p.T766Nfs*14 | Frame Shift Ins (INS) | VAF 15/79 reads (19%) | catalogued as rs749890836; called by mutect2, pindel, varscan2
- EVX2 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 108/566 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs1379226242, COSV57962786; called by mutect2, varscan2
- EYA1 | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 80/382 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CM081593, COSV58157975; called by muse, mutect2, varscan2
- EZH2 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as rs771352080, COSV57452692; called by muse, mutect2, varscan2
- F7 | c.1244C>T p.T415M | Missense Mutation (SNP) | VAF 49/284 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1205970958; called by muse, varscan2
- FAH | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 38/506 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs775156172, COSV55722940; called by muse, mutect2
- FARP1 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs755092202; called by muse, mutect2, varscan2
- FAT3 | c.5396G>A p.R1799Q | Missense Mutation (SNP) | VAF 74/360 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.074); catalogued as rs757999627, COSV99967065; called by muse, mutect2, varscan2
- FBLN7 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99735024; called by muse, mutect2, varscan2
- FERD3L | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV51762036; called by muse, mutect2, varscan2
- FLNA | c.2392G>A p.E798K | Missense Mutation (SNP) | VAF 97/529 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as rs782454177, COSV61037943; called by muse, mutect2, varscan2
- FRYL | c.4388del p.P1463Rfs*26 | Frame Shift Del (DEL) | VAF 30/151 reads (20%) | catalogued as COSV51961480; called by mutect2, pindel, varscan2
- GALNT13 | c.1543C>T p.R515* | Nonsense Mutation (SNP) | VAF 16/161 reads (10%) | catalogued as rs780336642, COSV101222521; called by muse, mutect2
- GAS6 | c.449del p.G150Afs*49 | Frame Shift Del (DEL) | VAF 37/157 reads (24%) | catalogued as rs773341392; called by mutect2, varscan2
- GBA | c.1358A>C p.Q453P | Missense Mutation (SNP) | VAF 34/521 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM057080; called by muse, mutect2
- GBP7 | c.1729C>T p.R577* | Nonsense Mutation (SNP) | VAF 41/172 reads (24%) | catalogued as rs376019280; called by muse, mutect2, varscan2
- GCM2 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 69/290 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.231); catalogued as COSV65275186; called by muse, mutect2, varscan2
- GGH | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs146984806; called by muse, mutect2, varscan2
- GJB6 | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs538884824, COSV53831864; called by muse, varscan2
- GLIS1 | c.216del p.T73Pfs*29 | Frame Shift Del (DEL) | VAF 23/88 reads (26%) | catalogued as rs1386928266; called by mutect2, pindel, varscan2
- GOT1 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs368072040; called by muse, mutect2, varscan2
- GP5 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 96/366 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.283); catalogued as COSV99757163; called by muse, mutect2, varscan2
- GPATCH2L | c.721C>T p.R241* | Nonsense Mutation (SNP) | VAF 18/100 reads (18%) | catalogued as rs769144967; called by muse, mutect2, varscan2
- GRB14 | c.985A>T p.S329C | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1231905538; called by muse, mutect2, varscan2
- GREB1L | c.1067C>T p.T356M | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.168); catalogued as rs369888713; called by muse, mutect2, varscan2
- GRIP2 | c.1264C>T p.R422W (on ENST00000619221; = p.R325W on NM_001080423.4) | Missense Mutation (SNP) | VAF 55/249 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs375948443; called by muse, mutect2, varscan2
- HAGHL | c.640del p.E214Rfs*15 | Frame Shift Del (DEL) | VAF 41/170 reads (24%) | catalogued as rs747918697; called by mutect2, varscan2
- HEATR1 | c.4732C>T p.R1578C | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs984400999; called by muse, mutect2, varscan2
- HECTD4 | c.13093G>A p.A4365T | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as rs768829841; called by muse, mutect2, varscan2
- HK3 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52842685; called by muse, mutect2
- HMCN2 | c.5116G>A p.V1706I | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.208); catalogued as rs764279393, COSV70382564, COSV70382953; called by muse, mutect2, varscan2
- HNRNPCL2 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV60402339; called by muse, mutect2, varscan2
- HNRNPDL | c.1229del p.G410Vfs*25 | Frame Shift Del (DEL) | VAF 20/77 reads (26%) | catalogued as COSV99040410; called by mutect2, pindel, varscan2
- HSF1 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1050279298; called by muse, mutect2, varscan2
- IFI27 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.189); catalogued as rs762435559; called by muse, mutect2, varscan2
- IGF2BP2 | c.905A>G p.H302R | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs750677541; called by muse, mutect2, varscan2
- IGF2R | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs754988891, COSV63631049; called by muse, mutect2, varscan2
- IGFALS | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 132/634 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as rs201622145; called by muse, mutect2, varscan2
- IGLV3-21 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); catalogued as rs1267055233; called by muse, mutect2
- IGSF3 | c.1237G>A p.V413M (on ENST00000369486 / NM_001007237.3; = p.V433M on NM_001542.4) | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as rs781166741; called by muse, mutect2, varscan2
- IRGQ | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as rs530949470; called by muse, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 19/100 reads (19%) | catalogued as rs761880048; called by mutect2, varscan2
- IRS4 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 10/322 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.531); catalogued as COSV100929848; called by muse, mutect2
- IRX1 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 108/524 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs569261954, COSV57361229, COSV57362969; called by mutect2, varscan2
- ISG15 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 28/156 reads (18%) | catalogued as rs367621226; called by muse, mutect2, varscan2
- ITGA8 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as COSV100959921; called by muse, mutect2, varscan2
- ITGAX | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs200320931, COSV51643641; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs528108942; called by muse, mutect2, varscan2
- KCND1 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs147309267, COSV54413677; called by muse, mutect2, varscan2
- KCNJ4 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs1471959235, COSV57856534; called by muse, mutect2, varscan2
- KCNQ2 | c.2087C>T p.T696M (on ENST00000359125 / NM_172107.4; = p.T668M on NM_004518.6) | Missense Mutation (SNP) | VAF 49/216 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs570139975; ClinVar: benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- KCNQ2 | c.1955del p.P652Rfs*278 (on ENST00000359125 / NM_172107.4; = p.P624Rfs*278 on NM_004518.6) | Frame Shift Del (DEL) | VAF 39/270 reads (14%) | catalogued as COSV60550914; called by mutect2, pindel, varscan2
- KDM4B | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV50241714; called by muse, mutect2, varscan2
- KDM5B | c.4618G>A p.A1540T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs776901690, COSV52506406; called by muse, varscan2
- KHDRBS1 | c.1223A>G p.Y408C | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777403559; called by muse, mutect2, varscan2
- KIAA0586 | c.623G>A p.R208H (on ENST00000619416 / NM_001244190.2; = p.R223H on NM_014749.5) | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.938); catalogued as rs779062959; called by muse, mutect2, varscan2
- KIAA1109 | c.11477G>A p.R3826Q | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs201970061, COSV99151693; called by muse, mutect2, varscan2
- KLHL18 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as rs758466622; called by muse, mutect2, varscan2
- KMT2D | c.10394dup p.P3466Tfs*2 | Frame Shift Ins (INS) | VAF 31/218 reads (14%) | catalogued as rs1284500089; called by mutect2, pindel, varscan2
- KRT12 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1279030895, COSV52430869; called by muse, mutect2, varscan2
- KY | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 72/356 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as rs750351662, COSV71018091; called by muse, mutect2, varscan2
- LAMC1 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.659); catalogued as rs374634622; called by muse, mutect2, varscan2
- LARP1 | c.906del p.T303Pfs*23 (on ENST00000518297 / NM_033551.3; = p.T226Pfs*23 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 24/121 reads (20%) | catalogued as rs769338468, COSV60425051; called by mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 16/97 reads (16%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LEPR | c.3317C>T p.A1106V | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as rs769027063; called by muse, mutect2, varscan2
- LINGO1 | c.1453C>T p.R485C | Missense Mutation (SNP) | VAF 128/438 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs776394148, COSV62437156; called by muse, mutect2, varscan2
- LRP2 | c.12316C>T p.R4106* | Nonsense Mutation (SNP) | VAF 110/488 reads (23%) | catalogued as rs747910703, COSV99785860; called by muse, mutect2, varscan2
- LRP2 | c.6038G>A p.R2013H | Missense Mutation (SNP) | VAF 84/368 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs201371915; called by muse, mutect2, varscan2
- LRP2 | c.4999C>T p.R1667* | Nonsense Mutation (SNP) | VAF 48/276 reads (17%) | catalogued as rs867941074, COSV55558193; called by muse, mutect2, varscan2
- LRRC24 | c.389C>A p.A130E | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1224660412; called by muse, mutect2
- LRRC70 | c.1550G>C p.C517S | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs978878827; called by muse, mutect2, varscan2
- LZTS2 | c.350A>G p.N117S | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1193207002; called by muse, mutect2, varscan2
- MAP3K11 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1052224019, COSV58421911; called by muse, mutect2, varscan2
- MAPK12 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.937); catalogued as rs369173418; called by muse, mutect2, varscan2
- MAPK4 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV101245868; called by muse, mutect2, varscan2
- MAST1 | c.3503C>T p.A1168V | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as rs1213627092, COSV52249070; called by muse, mutect2
- MCF2L | c.1813C>T p.R605W (on ENST00000375608; = p.R573W on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs778131865, COSV100982593, COSV100982748; called by muse, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MERTK | c.2728G>A p.A910T | Missense Mutation (SNP) | VAF 76/387 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs755422343, COSV54933937; called by muse, mutect2, varscan2
- MFN2 | c.306del p.F102Lfs*11 | Frame Shift Del (DEL) | VAF 40/278 reads (14%) | catalogued as rs777012596; called by mutect2, pindel, varscan2
- MGAT5B | c.1897C>T p.R633W (on ENST00000569840 / NM_001199172.2; = p.R631W on NM_144677.3) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1295063912, COSV56926742; called by muse, mutect2, varscan2
- MIER3 | c.1027del p.R343Dfs*15 (on ENST00000381199 / NM_001297599.2; = p.R342Dfs*15 on NM_152622.4) | Frame Shift Del (DEL) | VAF 27/160 reads (17%) | catalogued as COSV67083276; called by mutect2, pindel, varscan2
- MMD2 | c.472G>T p.G158W | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.552); catalogued as rs1049571299; called by muse, mutect2, varscan2
- MMP9 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 27/710 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV63433768; called by muse, mutect2
- MOCS1 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 106/513 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs774298259, COSV51421329; called by muse, mutect2, varscan2
- MSI2 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.98); catalogued as rs1028735566; called by muse, mutect2, varscan2
- MUC16 | c.22315G>A p.A7439T | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV67469159; called by muse, mutect2, varscan2
- MUC16 | c.8254C>A p.P2752T | Missense Mutation (SNP) | VAF 28/386 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV101201785; called by muse, mutect2
- MUC19 | c.359A>G p.Y120C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs188272912; called by muse, mutect2, varscan2
- MXD4 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.041); catalogued as rs1395323149, COSV61465974; called by muse, mutect2, varscan2
- MYH2 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 64/308 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.545); catalogued as rs1359566884; called by muse, mutect2, varscan2
- MYO18A | c.5686G>A p.E1896K | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1292468178; called by muse, mutect2, varscan2
- MYO5A | c.2693G>A p.R898Q | Missense Mutation (SNP) | VAF 25/327 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs764683651; called by muse, mutect2
- MYO7B | c.5026C>T p.R1676W | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs758438016, COSV67348621; called by muse, mutect2, varscan2
- NAGK | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1170981133, COSV99730641; called by muse, mutect2, varscan2
- NALCN | c.3842C>T p.T1281M | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1304343682, COSV51950580; called by muse, mutect2, varscan2
- NAP1L3 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 70/332 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV59078151; called by muse, varscan2
- NAPEPLD | c.842T>C p.F281S | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1008762007, COSV100439928; called by mutect2, varscan2
- NBEA | c.3953G>A p.R1318H | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59762766; called by muse, mutect2, varscan2
- NDUFB8 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.485); catalogued as rs866796358; called by muse, mutect2
- NEB | c.4939G>A p.A1647T | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs566604130, COSV50898584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEU1 | c.692T>C p.L231P | Missense Mutation (SNP) | VAF 93/380 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as CM002811; called by muse, mutect2, varscan2
- NEXN | c.196_197dup p.W67Nfs*25 | Frame Shift Ins (INS) | VAF 19/112 reads (17%) | catalogued as rs750492151; called by mutect2, varscan2
- NIN | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.615); catalogued as rs772314635, COSV55404487; called by muse, mutect2, varscan2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs145147241; called by mutect2, varscan2
- NISCH | c.2507G>A p.R836H | Missense Mutation (SNP) | VAF 70/300 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.301); catalogued as rs367898298; called by muse, mutect2, varscan2
- NKG7 | c.16T>C p.S6P | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as rs1479845252; called by muse, mutect2
- NKRF | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs759684907, COSV58661316; called by muse, mutect2, varscan2
- NKX2-8 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.197); catalogued as COSV99352428; called by muse, varscan2
- NLRP7 | c.677T>C p.L226P | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60173368; called by muse, mutect2
- NOL4 | c.1696C>A p.L566I | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV52347405; called by muse, varscan2
- NOS2 | c.2110T>C p.W704R | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58227503; called by muse, mutect2, varscan2
- NOS3 | c.3400G>T p.E1134* | Nonsense Mutation (SNP) | VAF 18/100 reads (18%) | catalogued as COSV52494600; called by muse, mutect2, varscan2
- NOTCH1 | c.6392del p.G2131Afs*117 | Frame Shift Del (DEL) | VAF 50/256 reads (20%) | catalogued as rs1455334351; called by mutect2, varscan2
- NOTCH1 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.801); catalogued as rs775217381, COSV53054567; ClinVar: uncertain significance; called by muse, mutect2
- NPTXR | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV100285307; called by muse, mutect2, varscan2
- NR0B1 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 169/674 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as COSV66764851; called by muse, mutect2, varscan2
- NR0B1 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 83/450 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.04); catalogued as rs202123604; called by muse, mutect2, varscan2
- NR0B2 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.879); catalogued as COSV54259620; called by muse, mutect2, varscan2
- NSD2 | c.3515G>A p.G1172E | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs770661384; called by muse, mutect2, varscan2
- NUP85 | c.1680_1682del p.L561del | In Frame Del (DEL) | VAF 49/317 reads (15%) | catalogued as rs759765425; called by mutect2, pindel, varscan2
- NUTM2B | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 77/350 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.234); catalogued as rs1360287268; called by muse, mutect2, varscan2
- NXPE3 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.825); catalogued as rs754510979, COSV56290427; called by muse, mutect2, varscan2
- OAS1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs377100213; called by muse, mutect2, varscan2
- OR10A6 | c.62C>A p.P21H | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1379524428; called by muse, mutect2, varscan2
- OR10C1 | c.766G>A p.A256T (on ENST00000622521; = p.A254T on NM_013941.3) | Missense Mutation (SNP) | VAF 80/417 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs374582900, COSV65824422; called by muse, mutect2, varscan2
- OR1J1 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 50/309 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.125); catalogued as rs762965619, COSV52237360, COSV52239396; called by muse, mutect2, varscan2
- OR4P4 | c.315del p.F105Lfs*4 | Frame Shift Del (DEL) | VAF 58/183 reads (32%) | catalogued as rs748398423; called by mutect2, varscan2
- OR52M1 | c.181A>G p.M61V | Missense Mutation (SNP) | VAF 44/265 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as rs921381330; called by muse, mutect2, varscan2
- PAFAH1B1 | c.1051A>G p.K351E | Missense Mutation (SNP) | VAF 45/244 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs1345313290, COSV68210690; called by muse, mutect2, varscan2
- PAK1IP1 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.27); catalogued as rs750701531; called by muse, mutect2, varscan2
- PAK5 | c.1834C>A p.P612T | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62028339; called by muse, mutect2
- PAPLN | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs930664832, COSV53721673; called by muse, mutect2, varscan2
- PAX5 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs935667573; called by muse, mutect2, varscan2
- PCDH17 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 15/474 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV64971920; called by muse, mutect2
- PCDHB14 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 138/594 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.036); catalogued as rs151163282; called by muse, mutect2, varscan2
- PCDHB7 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.91); catalogued as rs782364415, COSV50762092; called by muse, mutect2, varscan2
- PCDHGA8 | c.2203G>A p.V735M | Missense Mutation (SNP) | VAF 61/292 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.029); catalogued as COSV54065030; called by muse, mutect2, varscan2
- PCDHGB1 | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 49/408 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.313); catalogued as COSV53902592; called by muse, mutect2, varscan2
- PCLO | c.12388C>T p.Q4130* | Nonsense Mutation (SNP) | VAF 78/360 reads (22%) | catalogued as COSV61663555; called by muse, mutect2, varscan2
- PDCD11 | c.5458C>T p.R1820W | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757099554, COSV53294575; called by muse, mutect2, varscan2
- PER2 | c.272A>G p.N91S | Missense Mutation (SNP) | VAF 18/397 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs1466928324; called by muse, mutect2
- PER3 | c.3340C>T p.R1114C | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs750738867; called by muse, mutect2, varscan2
- PEX5 | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 97/521 reads (19%) | catalogued as rs777733574; called by muse, mutect2, varscan2
- PHACTR1 | c.759dup p.P254Afs*78 | Frame Shift Ins (INS) | VAF 34/178 reads (19%) | catalogued as rs749326031; called by mutect2, varscan2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PHB2 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 79/362 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs782047418; called by muse, mutect2, varscan2
- PHLPP1 | c.4927G>A p.A1643T | Missense Mutation (SNP) | VAF 43/254 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV53024714; called by muse, varscan2
- PI16 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 90/357 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs1369919578, COSV65321183; called by muse, mutect2, varscan2
- PKD1 | c.7456G>A p.A2486T | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.344); catalogued as rs567983155; ClinVar: uncertain significance; called by muse, mutect2
- PLA2R1 | c.3659G>A p.S1220N | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.66); catalogued as COSV51780677; called by muse, mutect2, varscan2
- PLAT | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 6/156 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54276168, COSV54277811; called by muse, mutect2
- PLPP1 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1045443300; called by muse, mutect2, varscan2
- PLXNB1 | c.536del p.G179Vfs*41 | Frame Shift Del (DEL) | VAF 56/246 reads (23%) | catalogued as rs953293505; called by mutect2, varscan2
- POLE | c.2091del p.L698Cfs*94 | Frame Shift Del (DEL) | VAF 14/146 reads (10%) | catalogued as rs752846614; ClinVar: uncertain significance; called by mutect2, pindel
- PPEF2 | c.1827G>A p.M609I | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as rs780016233; called by muse, mutect2, varscan2
- PPP1R12C | c.879G>A p.G293= | Splice Region (SNP) | VAF 26/136 reads (19%) | catalogued as rs1444040659; called by muse, mutect2, varscan2
- PPP1R3A | c.1946G>T p.S649I | Missense Mutation (SNP) | VAF 97/712 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52878369; called by muse, mutect2, varscan2
- PPP2R5A | c.*7del | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as rs540232176; called by mutect2, varscan2
- PRF1 | c.1428del p.L478* | Frame Shift Del (DEL) | VAF 70/414 reads (17%) | catalogued as rs748926167, CD132539, COSV100942602; called by mutect2, pindel, varscan2
- PRG2 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs749818783; called by muse, mutect2, varscan2
- PRX | c.4192G>A p.A1398T | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs1315686781; called by muse, mutect2, varscan2
- PSEN2 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 30/493 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201494033, COSV60918526; called by muse, mutect2
- QARS1 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 17/378 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs867275185, COSV60274722; called by muse, mutect2
- RABEP2 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 48/239 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs752673497; called by muse, mutect2, varscan2
- RALB | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776654341; called by muse, mutect2, varscan2
- RBM17 | c.929G>T p.R310M | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV101159221; called by mutect2, varscan2
- RBM20 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 126/636 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV65705961; called by muse, mutect2, varscan2
- RBM41 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757123103, COSV99179825; called by muse, mutect2, varscan2
- RBMXL2 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs759671784, COSV100182482; called by muse, mutect2, varscan2
- RECQL | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs566339459, COSV57553564; called by mutect2, varscan2
- REV3L | c.8156C>T p.A2719V | Missense Mutation (SNP) | VAF 61/297 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs376298082; called by muse, mutect2, varscan2
- RGMB | c.1016G>A p.R339H (on ENST00000513185 / NM_001366508.1; = p.R380H on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/378 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs527774662, COSV57564714; called by muse, mutect2, varscan2
- RGS12 | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.849); catalogued as rs759834164, COSV60674307; called by muse, mutect2, varscan2
- RGS12 | c.2633G>A p.R878Q | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771934019; called by muse, mutect2, varscan2
- RMDN3 | c.1156del p.T386Lfs*22 | Frame Shift Del (DEL) | VAF 29/97 reads (30%) | catalogued as rs745408248; called by mutect2, varscan2
- RNF165 | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53978411; called by muse, mutect2, varscan2
- RNF214 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs780542286; called by muse, mutect2
- RNF34 | c.633+11del | Splice Region (DEL) | VAF 27/117 reads (23%) | catalogued as rs1239453086; called by mutect2, pindel, varscan2
- ROBO2 | c.2456G>A p.S819N | Missense Mutation (SNP) | VAF 48/380 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.199); catalogued as COSV59895867; called by muse, mutect2, varscan2
- RPRD1B | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100987333, COSV65034154; called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.137T>C p.M46T | Missense Mutation (SNP) | VAF 10/231 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.34); catalogued as rs1360860961; called by muse, mutect2
- RRAS | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 94/354 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs1358894507; called by muse, mutect2, varscan2
- RRP9 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as rs41292346; called by muse, mutect2, varscan2
- RSPO4 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs377299234; called by muse, mutect2, varscan2
- RTP5 | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs763494394; called by muse, mutect2, varscan2
- RWDD4 | c.204del p.F68Lfs*9 | Frame Shift Del (DEL) | VAF 30/133 reads (23%) | catalogued as rs1325913157; called by mutect2, pindel, varscan2
- RXRA | c.331del p.L111Wfs*57 | Frame Shift Del (DEL) | VAF 36/173 reads (21%) | catalogued as COSV62684236; called by pindel, varscan2
- RYR3 | c.13625C>T p.P4542L (on ENST00000389232; = p.P4543L on NM_001036.6) | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.203); catalogued as rs1325751097, COSV66799722; called by muse, mutect2, varscan2
- SAP30BP | c.549+4C>T | Splice Region (SNP) | VAF 32/163 reads (20%) | catalogued as rs773183461; called by mutect2, varscan2
- SBNO2 | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs751771586; called by muse, mutect2, varscan2
- SCARA3 | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201948380, COSV57269420; called by muse, mutect2, varscan2
- SCN3A | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs965476894, COSV51822082; ClinVar: uncertain significance; called by muse, mutect2
- SCN5A | c.3541G>A p.V1181M (on ENST00000333535 / NM_198056.3; = p.V1180M on NM_000335.5) | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as rs794728874; called by muse, mutect2, varscan2
- SCRN3 | c.235dup p.A79Gfs*7 | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | catalogued as rs1326204105; called by mutect2, varscan2
- SDK1 | c.4246C>T p.R1416C | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.278); catalogued as rs767144879; called by muse, mutect2, varscan2
- SDK1 | c.5819G>A p.R1940Q | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as rs138555477; called by muse, mutect2, varscan2
- SEL1L3 | c.2393C>T p.A798V | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762938975, COSV53548589; called by muse, mutect2, varscan2
- SETD2 | c.6011A>G p.D2004G | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1444726256; called by muse, mutect2, varscan2
- SFRP4 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 76/297 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.337); catalogued as COSV52261958; called by muse, mutect2, varscan2
- SH3BP5 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs763770253; called by muse, mutect2
- SHOC1 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758283416; called by muse, mutect2, varscan2
- SHROOM2 | c.2560G>A p.A854T | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as rs1255541310; called by muse, mutect2, varscan2
- SIN3A | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100845242; called by muse, mutect2
- SIPA1L3 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 66/233 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.155); catalogued as rs747386407; called by muse, mutect2, varscan2
- SIPA1L3 | c.2317G>A p.A773T | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as rs763529744; called by muse, mutect2, varscan2
- SKIV2L | c.2446del p.E816Rfs*3 | Frame Shift Del (DEL) | VAF 34/197 reads (17%) | catalogued as rs768446878; called by mutect2, pindel, varscan2
- SLC12A6 | c.3248G>A p.R1083Q (on ENST00000354181 / NM_001365088.1; = p.R1032Q on NM_005135.2) | Missense Mutation (SNP) | VAF 77/198 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as rs567361041; called by muse, mutect2, varscan2
- SLC1A7 | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 95/478 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs147574179; called by muse, mutect2, varscan2
- SLC4A10 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 30/181 reads (17%) | catalogued as rs899870875; called by muse, mutect2, varscan2
- SLC4A2 | c.1151C>A p.A384D | Missense Mutation (SNP) | VAF 15/346 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV59656788; called by muse, mutect2
- SLC6A17 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs752449076, COSV100521412, COSV58994713; called by muse, mutect2, varscan2
- SMYD1 | c.361C>T p.L121F | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.161); catalogued as rs1275384540; called by muse, mutect2, varscan2
- SND1 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV61248045; called by muse, mutect2, varscan2
- SPAG17 | c.5275A>G p.S1759G | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1238242052; called by mutect2, varscan2
- SPRY3 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs779201129, COSV57142048; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPRY4 | c.184A>G p.T62A (on ENST00000434127 / NM_001127496.3; = p.T85A on NM_030964.4) | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs977529367; called by muse, mutect2, varscan2
- SRGAP1 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); catalogued as rs773750433; called by muse, mutect2, varscan2
- SSTR5 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs994272194; called by muse, mutect2, varscan2
- STARD8 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs777610643, COSV52927495; called by muse, mutect2, varscan2
- SUGP2 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58256470, COSV58264340; called by muse, mutect2, varscan2
- SVIL | c.2185C>T p.R729C (on ENST00000355867 / NM_021738.3; = p.R335C on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs536836258, COSV63445215; called by muse, mutect2, varscan2
- SYNE2 | c.1876G>A p.A626T | Missense Mutation (SNP) | VAF 58/261 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766378548, COSV59968960; called by muse, mutect2, varscan2
- SYNJ2 | c.554T>C p.I185T | Missense Mutation (SNP) | VAF 38/337 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.836); catalogued as rs754151212; called by muse, mutect2, varscan2
- TAF1B | c.834del p.Y278* | Frame Shift Del (DEL) | VAF 32/166 reads (19%) | catalogued as COSV55155775, COSV99721849; called by mutect2, varscan2
- TAF1C | c.2370del p.T791Rfs*8 | Frame Shift Del (DEL) | VAF 38/176 reads (22%) | catalogued as rs763039552; called by mutect2, varscan2
- TANC2 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs202242128; called by muse, mutect2, varscan2
- TCHP | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 17/97 reads (18%) | catalogued as rs753327632; called by muse, mutect2, varscan2
- TEAD1 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 32/518 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.691); catalogued as rs866303048; called by muse, mutect2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 40/134 reads (30%) | catalogued as rs763321097; called by mutect2, varscan2
- TENM1 | c.6512G>A p.R2171H | Missense Mutation (SNP) | VAF 60/326 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762426434, COSV64428703; called by muse, mutect2, varscan2
- TENM2 | c.1579C>T p.R527C (on ENST00000518659 / NM_001122679.2; = p.R295C on NM_001080428.3) | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as rs972252567, COSV101317711; called by muse, mutect2
- TENM3 | c.2082dup p.T695Dfs*5 | Frame Shift Ins (INS) | VAF 18/60 reads (30%) | catalogued as rs758217137; called by mutect2, varscan2
- TEP1 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1463534447; called by muse, mutect2
- TET2 | c.3640C>T p.R1214W | Missense Mutation (SNP) | VAF 67/309 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761811530, COSV54395395; called by muse, mutect2, varscan2
- TEX101 | c.187A>G p.T63A (on ENST00000598265 / NM_001130011.3; = p.T81A on NM_031451.4) | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as COSV53662173, COSV53663419; called by muse, mutect2
- TEX44 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 91/417 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs1309290783; called by muse, mutect2, varscan2
- TH | c.12del p.D5Tfs*27 (on ENST00000381178 / NM_199292.3; = p.D5Tfs*78 on NM_000360.4) | Frame Shift Del (DEL) | VAF 64/280 reads (23%) | catalogued as COSV60766651; called by mutect2, varscan2
- TJP3 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs763444158, COSV53662858; called by muse, mutect2, varscan2
- TKTL2 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV54920839, COSV54921094; called by muse, mutect2, varscan2
- TMEM132A | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 80/411 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.267); catalogued as rs769708258; called by muse, mutect2, varscan2
- TNC | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 32/526 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs150548325, COSV60792027; called by muse, mutect2
- TNFAIP1 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs571193496; called by muse, mutect2, varscan2
- TNPO1 | c.2530del p.C844Vfs*45 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | catalogued as rs757314136; called by mutect2, varscan2
- TNS2 | c.1484del p.P495Rfs*25 (on ENST00000314250 / NM_170754.4; = p.P505Rfs*25 on NM_015319.2) | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as rs758743608; called by mutect2, pindel, varscan2
- TRAF3IP3 | c.1576C>T p.R526* | Nonsense Mutation (SNP) | VAF 6/107 reads (6%) | catalogued as rs1470581004, COSV50551177; called by muse, mutect2
- TRAK1 | c.1965G>A p.A655= | Splice Region (SNP) | VAF 20/106 reads (19%) | catalogued as rs545460609, COSV59638775; called by muse, mutect2, varscan2
- TRAPPC5 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs1395925604; called by muse, mutect2, varscan2
- TRDN | c.1050del p.E351Sfs*13 | Frame Shift Del (DEL) | VAF 14/109 reads (13%) | catalogued as rs753514580; called by mutect2, varscan2
- TRIM55 | c.937A>C p.N313H | Missense Mutation (SNP) | VAF 7/178 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV99396473; called by muse, mutect2
- TRIM64B | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 104/969 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs761818237, COSV61694147; called by muse, mutect2, varscan2
- TRIO | c.4227G>T p.Q1409H | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV100711257; called by muse, mutect2, varscan2
- TRO | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs935196884, COSV51500417; called by muse, mutect2
- TSHZ3 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 42/299 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as rs769727817; called by muse, mutect2, varscan2
- TSNARE1 | c.543_545del p.V182del | In Frame Del (DEL) | VAF 22/121 reads (18%) | catalogued as rs751189979; called by mutect2, pindel, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs760251146; called by mutect2, varscan2
- TWIST1 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 71/344 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867957820, CD992486, CM156025; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TYW1B | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs782650215; called by muse, mutect2, varscan2
- UBFD1 | c.684A>C p.K228N | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99563502; called by muse, mutect2, varscan2
- UCHL3 | c.629A>G p.K210R | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0.054); catalogued as rs150677527; called by muse, varscan2
- ULK2 | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as rs760247958; called by muse, mutect2, varscan2
- UNC13B | c.4021C>T p.R1341* | Nonsense Mutation (SNP) | VAF 44/219 reads (20%) | catalogued as rs549111622; called by muse, mutect2, varscan2
- UROC1 | c.920del p.K307Rfs*77 | Frame Shift Del (DEL) | VAF 50/356 reads (14%) | catalogued as rs754361807; called by mutect2, varscan2
- USH2A | c.14917G>A p.V4973M | Missense Mutation (SNP) | VAF 47/233 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs201426385; called by muse, mutect2, varscan2
- USP17L1 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 20/536 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.127); catalogued as rs1015060117; called by muse, mutect2
- USP39 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs773871254; called by muse, mutect2, varscan2
- VCAN | c.2557G>A p.E853K | Missense Mutation (SNP) | VAF 69/407 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV54097528; called by muse, mutect2, varscan2
- VCAN | c.4004-4T>C | Splice Region (SNP) | VAF 22/139 reads (16%) | catalogued as COSV99427353; called by muse, mutect2, varscan2
- VIPR1 | c.215G>A p.C72Y | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477759214; called by muse, mutect2, varscan2
- VPS51 | c.73del p.E25Rfs*13 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as rs1215813683, COSV99661065; called by mutect2, pindel, varscan2
- WDR19 | c.3172G>A p.A1058T | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as rs768769727; called by muse, mutect2, varscan2
- WDR33 | c.3007C>T p.R1003C | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as rs112341522, COSV100460008; called by muse, mutect2, varscan2
- WDR73 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs748057659, COSV62411321; called by muse, mutect2, varscan2
- WLS | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 26/126 reads (21%) | catalogued as rs763193261, COSV99259075; called by muse, mutect2, varscan2
- WNK4 | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 93/397 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as rs200182836; ClinVar: benign; called by muse, mutect2, varscan2
- WNT7A | c.833G>A p.C278Y | Missense Mutation (SNP) | VAF 109/463 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1320156631; called by muse, mutect2, varscan2
- WSCD1 | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 74/313 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs555191416; called by muse, mutect2, varscan2
- WSCD2 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 86/255 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV54580843; called by muse, mutect2, varscan2
- WWP2 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.565); catalogued as rs369381187; called by muse, mutect2, varscan2
- XAB2 | c.802C>A p.R268S | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766031691, COSV100601644, COSV100601891; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 49/232 reads (21%) | catalogued as rs779864368; called by mutect2, varscan2
- YME1L1 | c.1286C>T p.A429V (on ENST00000326799 / NM_139312.3; = p.A372V on NM_014263.4) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.605); catalogued as rs746446455, COSV58760011; called by muse, mutect2, varscan2
- ZBBX | c.975del p.K325Nfs*55 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as rs773705832; called by mutect2, pindel, varscan2
- ZBED8 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs200826652, COSV68824387; called by muse, mutect2, varscan2
- ZBTB18 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 20/287 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs201655512, COSV100700276; called by muse, mutect2
- ZBTB40 | c.3521C>T p.A1174V | Missense Mutation (SNP) | VAF 86/344 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776709448, COSV65144674; called by muse, mutect2, varscan2
- ZC3HAV1 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1159185212, COSV99648871; called by muse, mutect2, varscan2
- ZDHHC3 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs753044925; called by muse, mutect2, varscan2
- ZIC4 | c.917T>A p.L306H | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); catalogued as COSV101267799; called by muse, mutect2, varscan2
- ZIM3 | c.1318del p.T440Pfs*98 | Frame Shift Del (DEL) | VAF 33/211 reads (16%) | catalogued as rs760126796, COSV99517559, COSV99518191, COSV99518981; called by mutect2, pindel, varscan2
- ZNF320 | c.1184G>A p.S395N | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1218718092; called by muse, mutect2, varscan2
- ZNF330 | c.14del p.K5Rfs*18 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | catalogued as rs770975379; called by mutect2, varscan2
- ZNF536 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1223055764, COSV62831990, COSV62835027; called by muse, mutect2, varscan2
- ZNF576 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 67/308 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as rs752666812; called by muse, mutect2, varscan2
- ZNF652 | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs879168380; called by muse, mutect2
- ZNF830 | c.753del p.F251Lfs*6 | Frame Shift Del (DEL) | VAF 25/153 reads (16%) | catalogued as rs749765261; called by mutect2, varscan2
- ZNF875 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 62/245 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs759877031, COSV60992431, COSV60994517; called by muse, mutect2, varscan2
- ABCA4 | c.1677G>A p.W559* | Nonsense Mutation (SNP) | VAF 14/504 reads (3%) | called by muse, mutect2
- ABCB4 | c.1591G>T p.A531S | Missense Mutation (SNP) | VAF 17/316 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); called by muse, mutect2
- ABCC3 | c.3767C>T p.A1256V | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACSBG1 | c.1685T>A p.I562N | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ACTR3B | c.703del p.C235Afs*4 | Frame Shift Del (DEL) | VAF 32/187 reads (17%) | called by pindel, varscan2
- ADAMTSL3 | c.619C>A p.Q207K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ADGRL1 | c.1255C>A p.P419T (on ENST00000340736 / NM_001008701.3; = p.P414T on NM_014921.5) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- AFAP1L2 | c.1148A>G p.Y383C | Missense Mutation (SNP) | VAF 13/259 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- AIFM2 | c.896G>A p.G299D | Missense Mutation (SNP) | VAF 79/478 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AKAP11 | c.1481G>A p.S494N | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- AKAP11 | c.3737del p.L1246* | Frame Shift Del (DEL) | VAF 30/172 reads (17%) | called by mutect2, pindel, varscan2
- AKAP3 | c.335G>T p.R112M | Missense Mutation (SNP) | VAF 29/290 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.048); called by muse, mutect2
- AKAP9 | c.10647A>C p.K3549N (on ENST00000359028; = p.K3525N on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- AL645922.1 | c.1625_1626insT p.E542Dfs*86 | Frame Shift Ins (INS) | VAF 87/602 reads (14%) | called by mutect2, pindel, varscan2
- ANAPC2 | c.2165A>G p.Q722R | Missense Mutation (SNP) | VAF 63/280 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ANK1 | c.3970G>T p.A1324S | Missense Mutation (SNP) | VAF 23/541 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2
- ANKEF1 | c.1269del p.G424Efs*32 | Frame Shift Del (DEL) | VAF 51/251 reads (20%) | called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.2013G>A p.M671I | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- AP1S1 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- AP5B1 | c.2005G>T p.G669W | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- AP5S1 | c.50A>T p.D17V | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ARAP3 | c.2228del p.P743Hfs*47 | Frame Shift Del (DEL) | VAF 26/118 reads (22%) | called by mutect2, varscan2
- ARHGAP28 | c.179A>G p.H60R | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASH2L | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ASTN1 | c.1217G>T p.C406F | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ATF7IP | c.959del p.N320Mfs*7 | Frame Shift Del (DEL) | VAF 32/236 reads (14%) | called by mutect2, pindel, varscan2
- ATP13A4 | c.2811T>G p.D937E | Missense Mutation (SNP) | VAF 10/241 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ATP1A4 | c.1970C>A p.P657H | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ATRNL1 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AURKAIP1 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 146/434 reads (34%) | called by pindel, varscan2
- B3GALT2 | c.1042C>A p.L348I | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- B4GALNT3 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2
- BASP1 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BCAR3 | c.1196T>C p.L399P | Missense Mutation (SNP) | VAF 110/484 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- BST1 | c.50A>T p.Q17L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTBD18 | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- BUB3 | c.808_809del p.C270Pfs*16 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | called by pindel, varscan2
- C14orf93 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- C16orf91 | c.244dup p.L82Pfs*36 | Frame Shift Ins (INS) | VAF 75/328 reads (23%) | called by mutect2, varscan2
- C1GALT1C1L | c.590G>C p.R197T | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.083); called by muse, mutect2
- C6orf120 | c.278A>G p.E93G | Missense Mutation (SNP) | VAF 37/622 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.1); called by muse, mutect2
- C7orf61 | c.64-1G>T p.X22_splice | Splice Site (SNP) | VAF 68/344 reads (20%) | called by mutect2, varscan2
- CA7 | c.449del p.L150Wfs*10 | Frame Shift Del (DEL) | VAF 19/92 reads (21%) | called by mutect2, pindel, varscan2
- CABYR | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.253); called by muse, mutect2
- CACNA2D3 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- CACNG7 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- CASP14 | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CCDC144A | c.153C>A p.Y51* | Nonsense Mutation (SNP) | VAF 38/155 reads (25%) | called by muse, mutect2, varscan2
- CCDC198 | c.851A>T p.E284V | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CCDC58 | c.218del p.N73Tfs*3 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | called by mutect2, varscan2
- CCDC9 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- CCS | c.475del p.Q159Rfs*30 | Frame Shift Del (DEL) | VAF 13/78 reads (17%) | called by mutect2, pindel, varscan2
- CD34 | c.139G>T p.G47* | Nonsense Mutation (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
- CDK1 | c.653+2_653+5delinsCAG p.X218_splice | Splice Site (DEL) | VAF 21/85 reads (25%) | called by mutect2*, pindel, varscan2*
- CDKN2AIPNL | c.43del p.S15Rfs*63 | Frame Shift Del (DEL) | VAF 12/80 reads (15%) | called by mutect2, pindel, varscan2
- CEACAM4 | c.676C>A p.L226I | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- CELA3B | c.622del p.D208Tfs*28 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | called by mutect2, pindel, varscan2
- CENPC | c.1967C>A p.P656H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- CENPK | c.232del p.T78Hfs*7 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, varscan2
- CGNL1 | c.1660A>G p.T554A | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.573); called by muse, mutect2
- CHADL | c.277C>A p.L93M | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); called by muse, mutect2
- CHD1 | c.1601del p.L534Yfs*3 | Frame Shift Del (DEL) | VAF 65/260 reads (25%) | called by mutect2, pindel, varscan2
- CHRDL1 | c.340A>G p.T114A (on ENST00000372045; = p.T120A on NM_145234.4) | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- CHRM5 | c.288G>T p.W96C | Missense Mutation (SNP) | VAF 143/384 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CIC | c.4586del p.P1529Lfs*91 | Frame Shift Del (DEL) | VAF 90/439 reads (21%) | called by mutect2, pindel, varscan2
- CILK1 | c.215del p.N72Mfs*11 | Frame Shift Del (DEL) | VAF 23/146 reads (16%) | called by mutect2, pindel, varscan2
- COL9A2 | c.25del p.R9Afs*10 | Frame Shift Del (DEL) | VAF 17/157 reads (11%) | called by mutect2, pindel, varscan2
- CORO7 | c.1776C>T p.G592= | Splice Region (SNP) | VAF 12/266 reads (5%) | called by muse, mutect2
- CPA6 | c.1166dup p.N389Kfs*13 | Frame Shift Ins (INS) | VAF 14/81 reads (17%) | called by mutect2, pindel, varscan2
- CPT1A | c.1188G>T p.Q396H | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.516); called by muse, mutect2
- CRYBG3 | c.1947del p.K649Nfs*2 | Frame Shift Del (DEL) | VAF 26/99 reads (26%) | called by mutect2, varscan2
- CUEDC1 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- CWF19L2 | c.265_275delinsAGCAAAGAAAG p.A89_E92delinsSKER | Missense Mutation (ONP) | VAF 7/58 reads (12%) | called by pindel, varscan2*
- CXorf65 | c.55T>C p.C19R | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CYP3A4 | c.74A>G p.Y25C | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2
- DCLK2 | c.2073+1G>A p.X691_splice | Splice Site (SNP) | VAF 29/134 reads (22%) | called by muse, mutect2, varscan2
- DENND2C | c.724T>C p.S242P | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DGKA | c.77del p.K26Rfs*6 | Frame Shift Del (DEL) | VAF 22/149 reads (15%) | called by mutect2, pindel, varscan2
- DNAH3 | c.11441C>G p.T3814S | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- DOCK1 | c.3960del p.K1320Nfs*12 | Frame Shift Del (DEL) | VAF 20/151 reads (13%) | called by mutect2, pindel, varscan2
- DOCK9 | c.4002del p.F1334Lfs*19 (on ENST00000376460 / NM_001366676.2; = p.F1335Lfs*19 on NM_015296.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 23/105 reads (22%) | called by mutect2, pindel, varscan2
- DPP10 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2
- DPP3 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 36/346 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- DUSP10 | c.418A>G p.T140A | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- DUSP7 | c.626del p.G209Afs*131 | Frame Shift Del (DEL) | VAF 47/226 reads (21%) | called by mutect2, pindel, varscan2
- DXO | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- DYRK2 | c.1567C>T p.R523C (on ENST00000344096 / NM_006482.3; = p.R450C on NM_003583.4) | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ECE1 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 49/334 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- ECPAS | c.290T>C p.V97A | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- EEA1 | c.3245C>T p.T1082I | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- EEF1A1 | c.1157del p.K386Sfs*9 | Frame Shift Del (DEL) | VAF 22/220 reads (10%) | called by pindel, varscan2
- EFCAB6 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EGLN3 | c.164C>A p.A55D | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- EGR2 | c.779del p.P260Lfs*21 | Frame Shift Del (DEL) | VAF 34/328 reads (10%) | called by mutect2, pindel, varscan2
- EME1 | c.500G>A p.C167Y | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ENGASE | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ERAP1 | c.1033C>A p.L345I | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); called by muse, mutect2
- ERC2 | c.2060del p.K687Rfs*11 | Frame Shift Del (DEL) | VAF 14/114 reads (12%) | called by mutect2, pindel, varscan2
- ERFE | c.297C>A p.S99R | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.501); called by muse, mutect2
- FAIM2 | c.658T>C p.F220L | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.083); called by muse, mutect2
- FAM120A | c.1157del p.G386Afs*27 | Frame Shift Del (DEL) | VAF 48/206 reads (23%) | called by mutect2, varscan2
- FAM3A | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2
- FAR1 | c.49G>T p.G17* | Nonsense Mutation (SNP) | VAF 20/86 reads (23%) | called by muse, mutect2, varscan2
- FBXO33 | c.705del p.K236Nfs*11 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- FBXW11 | c.326C>A p.S109Y | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, varscan2
- FGD1 | c.2788A>G p.T930A | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLAD1 | c.1556A>G p.D519G | Missense Mutation (SNP) | VAF 16/369 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); called by muse, mutect2
- FMN1 | c.2077A>G p.T693A (on ENST00000616417 / NM_001277313.2; = p.T470A on NM_001103184.4) | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2
- FSCB | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- FSTL4 | c.260G>A p.C87Y | Missense Mutation (SNP) | VAF 26/506 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GADD45GIP1 | c.410A>G p.Q137R | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GCGR | c.1259T>C p.L420P | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by mutect2, varscan2
- GIPR | c.542T>C p.M181T | Missense Mutation (SNP) | VAF 15/257 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2
- GLE1 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, varscan2
- GOLGA6L22 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 88/469 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- GOPC | c.50del p.G17Afs*54 | Frame Shift Del (DEL) | VAF 38/244 reads (16%) | called by mutect2, pindel, varscan2
- GORAB | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); called by muse, varscan2
- GPATCH2L | c.1237A>G p.K413E | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GRWD1 | c.170A>G p.Y57C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GZMM | c.774A>G p.*258Wext*25 | Nonstop Mutation (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2
- H4-16 | c.128del p.G43Afs*24 | Frame Shift Del (DEL) | VAF 37/308 reads (12%) | called by mutect2, pindel, varscan2
- HCAR1 | c.299C>A p.A100D | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2
- HDAC6 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 33/268 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- HINT3 | c.469T>G p.F157V | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- HIPK3 | c.186del p.Q63Rfs*23 | Frame Shift Del (DEL) | VAF 48/275 reads (17%) | called by mutect2, pindel, varscan2
- HMCN1 | c.1361A>G p.D454G | Missense Mutation (SNP) | VAF 64/327 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- HNRNPUL1 | c.1442T>A p.I481N | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2
- HOXB1 | c.428del p.P143Lfs*41 | Frame Shift Del (DEL) | VAF 79/378 reads (21%) | called by mutect2, varscan2
- HS6ST3 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 83/303 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSPA4L | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- HTRA4 | c.938A>G p.D313G | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); called by muse, mutect2
- HYDIN | c.8417A>G p.K2806R | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ICAM4 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 63/286 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IFIH1 | c.1773A>C p.K591N | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- IFIT3 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 95/386 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- IGSF9 | c.3111del p.S1038Pfs*35 (on ENST00000368094 / NM_001135050.2; = p.S1022Pfs*35 on NM_020789.4) | Frame Shift Del (DEL) | VAF 40/293 reads (14%) | called by mutect2, pindel, varscan2
- IL7 | c.361-2del p.X121_splice | Splice Site (DEL) | VAF 12/80 reads (15%) | called by mutect2, pindel, varscan2
- INF2 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 92/370 reads (25%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- INSC | c.1651C>A p.L551I | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- INSYN2A | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- IQCD | c.1010A>G p.Y337C | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IQGAP3 | c.2008T>C p.W670R | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IQSEC2 | c.3196C>A p.L1066I (on ENST00000642864 / NM_001111125.3; = p.L861I on NM_015075.2) | Missense Mutation (SNP) | VAF 98/475 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- ITGA2B | c.2534A>G p.Y845C | Missense Mutation (SNP) | VAF 86/451 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAD | c.1813del p.A605Pfs*14 | Frame Shift Del (DEL) | VAF 11/73 reads (15%) | called by mutect2, pindel, varscan2
- ITPK1 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITSN1 | c.3443C>T p.P1148L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.99); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITSN2 | c.2806T>G p.F936V | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- KALRN | c.2041A>G p.K681E | Missense Mutation (SNP) | VAF 54/313 reads (17%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KALRN | c.8637del p.F2880Sfs*28 (on ENST00000360013 / NM_001024660.4; = p.F1183Sfs*28 on NM_007064.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 61/325 reads (19%) | called by mutect2, pindel, varscan2
- KAT2A | c.208dup p.A70Gfs*35 | Frame Shift Ins (INS) | VAF 14/68 reads (21%) | called by mutect2, varscan2
- KDM2A | c.2688G>T p.E896D | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, varscan2
- KIF13B | c.2641C>T p.P881S | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); called by muse, mutect2
- KIF1C | c.1838del p.P613Hfs*27 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | called by mutect2, varscan2
- KIF5C | c.2445del p.S816Vfs*68 | Frame Shift Del (DEL) | VAF 27/154 reads (18%) | called by mutect2, pindel, varscan2
- KLHDC3 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- KMO | c.475A>C p.T159P | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- KMT2D | c.7885T>A p.S2629T | Missense Mutation (SNP) | VAF 86/241 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMTOR3 | c.227A>C p.N76T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, varscan2
- LBH | c.130-1G>T p.X44_splice | Splice Site (SNP) | VAF 24/134 reads (18%) | called by muse, mutect2, varscan2
- LEFTY1 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- LEPR | c.2396-2A>G p.X799_splice | Splice Site (SNP) | VAF 28/116 reads (24%) | called by muse, mutect2, varscan2
- LIFR | c.2267del p.L756* | Frame Shift Del (DEL) | VAF 46/275 reads (17%) | called by mutect2, pindel, varscan2
- LMOD3 | c.862A>G p.S288G | Missense Mutation (SNP) | VAF 36/251 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- LRRC34 | c.176A>G p.N59S | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- LRRC41 | c.1034del p.P345Qfs*44 | Frame Shift Del (DEL) | VAF 20/120 reads (17%) | called by mutect2, varscan2
- MACF1 | c.10087T>G p.F3363V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- MAF | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 195/791 reads (25%) | called by muse, mutect2, varscan2
- MAGEB4 | c.144T>A p.D48E | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- MAN2B2 | c.3001A>G p.T1001A | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MAPK8 | c.946C>T p.L316F | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MB21D2 | c.692T>C p.M231T | Missense Mutation (SNP) | VAF 101/519 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- MEGF6 | c.1481A>C p.E494A | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.366); called by muse, mutect2
- MEIOC | c.1744del p.I582* | Frame Shift Del (DEL) | VAF 18/104 reads (17%) | called by mutect2, pindel, varscan2
- MINK1 | c.2972A>G p.K991R | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- MITF | c.917del p.K306Rfs*6 (on ENST00000448226 / NM_006722.3; = p.K206Rfs*6 on NM_000248.4) | Frame Shift Del (DEL) | VAF 31/182 reads (17%) | called by mutect2, pindel, varscan2
- MOB3B | c.377A>G p.E126G | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MUC12 | c.2890G>A p.E964K (on ENST00000379442; = p.E821K on NM_001164462.1) | Missense Mutation (SNP) | VAF 90/1456 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.301); called by muse, mutect2
- MUC16 | c.28719T>G p.I9573M | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); called by muse, mutect2
- MUC16 | c.26627G>A p.S8876N | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MYH9 | c.1633_1635del p.K545del | In Frame Del (DEL) | VAF 89/400 reads (22%) | called by mutect2, pindel, varscan2
- MYO18A | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- MYO1B | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- MYO1H | c.2200del p.R734Dfs*61 | Frame Shift Del (DEL) | VAF 22/124 reads (18%) | called by mutect2, varscan2
- NAP1L2 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.022); called by muse, mutect2
- NAPEPLD | c.1128dup p.V377Cfs*12 | Frame Shift Ins (INS) | VAF 10/59 reads (17%) | called by mutect2, varscan2
- NBEA | c.317T>C p.L106S | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NCF4 | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 30/477 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- NCOA2 | c.3212A>C p.E1071A | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- NECAP1 | c.635del p.P212Hfs*18 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- NES | c.1636C>A p.L546M | Missense Mutation (SNP) | VAF 35/278 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NEURL4 | c.3858_3859del p.C1286* | Nonsense Mutation (DEL) | VAF 22/103 reads (21%) | called by pindel, varscan2
- NFKB2 | c.2288C>A p.P763Q | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- NFU1 | c.361G>A p.V121I (on ENST00000410022 / NM_001002755.4; = p.V97I on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- NIN | c.1304del p.N435Mfs*19 | Frame Shift Del (DEL) | VAF 26/122 reads (21%) | called by mutect2, pindel, varscan2
- NLRC5 | c.5287A>G p.S1763G | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NLRP4 | c.1418C>A p.P473H | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NMRK1 | c.202T>C p.S68P | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- NOTCH1 | c.1399T>C p.C467R | Missense Mutation (SNP) | VAF 29/498 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NXF1 | c.80del p.G27Vfs*35 | Frame Shift Del (DEL) | VAF 18/103 reads (17%) | called by mutect2, pindel, varscan2
- OMD | c.11del p.L4* | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, varscan2
- OR10A3 | c.680A>C p.K227T | Missense Mutation (SNP) | VAF 56/242 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- OR10X1 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 64/312 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR14A16 | c.302del p.L101Cfs*15 | Frame Shift Del (DEL) | VAF 33/190 reads (17%) | called by mutect2, pindel, varscan2
- OR1E2 | c.925G>T p.A309S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- OR2A12 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 32/287 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.285); called by muse, mutect2
- OR2T10 | c.910del p.M304Cfs*2 | Frame Shift Del (DEL) | VAF 23/137 reads (17%) | called by mutect2, varscan2
- OR2T34 | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 28/412 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.028); called by muse, mutect2
- OR2T4 | c.908A>G p.D303G | Missense Mutation (SNP) | VAF 22/505 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2
- OR4C11 | c.817T>C p.Y273H | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- OR4C5 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 67/260 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PA2G4 | c.89-2A>G p.X30_splice | Splice Site (SNP) | VAF 7/50 reads (14%) | called by muse, varscan2
- PAQR5 | c.512+2T>C p.X171_splice | Splice Site (SNP) | VAF 30/93 reads (32%) | called by muse, mutect2, varscan2
- PARD3 | c.821T>C p.L274P | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2
- PC | c.947G>T p.R316M | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- PCDHGA9 | c.1615A>G p.S539G | Missense Mutation (SNP) | VAF 59/371 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PDE1C | c.1171A>C p.T391P | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDGFC | c.624G>A p.W208* | Nonsense Mutation (SNP) | VAF 41/206 reads (20%) | called by muse, mutect2, varscan2
- PDZD7 | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 68/408 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- PELP1 | c.820C>A p.L274M | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PERM1 | c.1274T>C p.V425A | Missense Mutation (SNP) | VAF 29/338 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.059); called by muse, mutect2
- PEX6 | c.2091del p.K698Rfs*16 | Frame Shift Del (DEL) | VAF 111/485 reads (23%) | called by mutect2, pindel, varscan2
- PIANP | c.310T>C p.W104R | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PIK3C2G | c.1210C>T p.Q404* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- PITX3 | c.860del p.P287Rfs*22 | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | called by mutect2, varscan2
- PKP3 | c.2334_2336del p.N778del | In Frame Del (DEL) | VAF 30/133 reads (23%) | called by pindel, varscan2
- PLBD1 | c.161T>C p.V54A | Missense Mutation (SNP) | VAF 127/352 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PLCD1 | c.329T>G p.L110R | Missense Mutation (SNP) | VAF 129/676 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PLEKHH3 | c.574dup p.V192Gfs*48 | Frame Shift Ins (INS) | VAF 20/99 reads (20%) | called by mutect2, pindel, varscan2
- PLSCR3 | c.242A>G p.Q81R | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- PNPLA6 | c.1930G>A p.A644T (on ENST00000414982 / NM_001166111.2; = p.A596T on NM_006702.5) | Missense Mutation (SNP) | VAF 54/344 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by mutect2, varscan2
- POLG | c.2948A>G p.Q983R | Missense Mutation (SNP) | VAF 147/377 reads (39%) | SIFT tolerated (0.99); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PPFIA2 | c.2679A>T p.L893F | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PPP2R2C | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPRC1 | c.282G>A p.M94I | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- PRAMEF14 | c.575T>A p.I192N | Missense Mutation (SNP) | VAF 116/424 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRDM8 | c.1050C>A p.C350* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- PRKDC | c.2446T>G p.S816A | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRRC2C | c.465A>T p.E155D (on ENST00000367742; = p.E153D on NM_015172.4) | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT tolerated (1); PolyPhen possibly damaging (0.621); called by muse, mutect2
- PSMD14 | c.347del p.P116Lfs*36 | Frame Shift Del (DEL) | VAF 21/134 reads (16%) | called by mutect2, pindel, varscan2
- PSMD8 | c.505G>C p.A169P | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- PTPRD | c.1447G>C p.V483L | Missense Mutation (SNP) | VAF 54/241 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PTX4 | c.1235del p.G412Afs*43 (on ENST00000447419 / NM_001328608.2; = p.G407Afs*43 on NM_001013658.1) | Frame Shift Del (DEL) | VAF 72/345 reads (21%) | called by mutect2, pindel, varscan2
- QTRT2 | c.1123G>T p.A375S | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2
- R3HDM1 | c.1310_1312del p.S437_H438delinsY | In Frame Del (DEL) | VAF 31/171 reads (18%) | called by mutect2, pindel, varscan2
- RAB19 | c.373A>G p.I125V | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAB40B | c.567G>A p.V189= | Splice Region (SNP) | VAF 23/90 reads (26%) | called by muse, mutect2, varscan2
- RABGGTB | c.230C>A p.S77Y | Missense Mutation (SNP) | VAF 84/416 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- RASAL3 | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.027); called by muse, mutect2
- RBM39 | c.556T>A p.S186T | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- RECQL5 | c.689A>G p.Q230R | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- REPS1 | c.2285del p.L762Wfs*4 (on ENST00000450536 / NM_001286611.2; = p.L761Wfs*4 on NM_031922.4) | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | called by mutect2, varscan2
- RFX1 | c.2764G>A p.D922N | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- RHBDF1 | c.1777_1778del p.V593Hfs*15 | Frame Shift Del (DEL) | VAF 26/130 reads (20%) | called by pindel, varscan2
- RHPN2 | c.635T>C p.L212P | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- RIC1 | c.3034A>G p.R1012G | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RUNX1 | c.943A>C p.I315L (on ENST00000344691 / NM_001001890.3; = p.I342L on NM_001754.5) | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SBF2 | c.2573T>C p.V858A | Missense Mutation (SNP) | VAF 17/207 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SCAMP5 | c.26C>A p.P9Q | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCGB1A1 | c.174_175insT p.G59Wfs*21 | Frame Shift Ins (INS) | VAF 10/80 reads (13%) | called by mutect2, pindel, varscan2
- SCN11A | c.4094G>T p.S1365I | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2
- SDK2 | c.6243del p.T2082Hfs*84 | Frame Shift Del (DEL) | VAF 23/105 reads (22%) | called by mutect2, pindel, varscan2
- SEL1L3 | c.2964del p.F988Lfs*6 | Frame Shift Del (DEL) | VAF 13/89 reads (15%) | called by mutect2, pindel, varscan2
- SEPTIN9 | c.464T>C p.V155A (on ENST00000427177 / NM_001113491.2; = p.V137A on NM_006640.4) | Missense Mutation (SNP) | VAF 32/454 reads (7%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); called by muse, mutect2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 32/80 reads (40%) | called by mutect2, varscan2
- SIPA1L1 | c.4285C>T p.R1429* | Nonsense Mutation (SNP) | VAF 70/241 reads (29%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- SLC17A7 | c.1246G>A p.G416S | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2
- SLC25A51 | c.659T>G p.L220R | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- SLC7A10 | c.1057C>A p.L353M | Missense Mutation (SNP) | VAF 11/262 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.13); called by muse, mutect2
- SLC9A6 | c.508-5_512delinsTTTCAGAGACAT p.X170_splice | Splice Site (INS) | VAF 8/48 reads (17%) | called by pindel, varscan2*
- SLC9A7 | c.950C>A p.A317D | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- SLF2 | c.3478C>T p.P1160S | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- SLTM | c.2585C>A p.P862H | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- SMAD2 | c.1235G>A p.C412Y | Missense Mutation (SNP) | VAF 13/320 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMO | c.2081del p.P694Lfs*82 | Frame Shift Del (DEL) | VAF 56/215 reads (26%) | called by mutect2, varscan2
- SNRK | c.1481A>G p.E494G | Missense Mutation (SNP) | VAF 27/381 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2
- SORBS2 | c.1371C>G p.H457Q | Missense Mutation (SNP) | VAF 89/449 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SOS2 | c.2731A>T p.K911* | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- SPI1 | c.133A>C p.S45R | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- SPOCK3 | c.1003G>T p.G335* | Nonsense Mutation (SNP) | VAF 27/143 reads (19%) | called by muse, mutect2, varscan2
- SPTBN2 | c.3502C>A p.L1168M | Missense Mutation (SNP) | VAF 75/375 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPTBN4 | c.3414G>T p.E1138D | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SPTBN5 | c.7738C>T p.L2580= | Splice Region (SNP) | VAF 71/153 reads (46%) | called by muse, mutect2, varscan2
- SRCIN1 | c.3034del p.R1012Efs*13 (on ENST00000621492; = p.R978Efs*13 on NM_025248.3) | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel
- SRGAP2 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); called by muse, varscan2
- ST8SIA5 | c.585dup p.I196Hfs*119 | Frame Shift Ins (INS) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- STAG3 | c.1510T>C p.C504R | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.117); called by muse, varscan2
- STARD9 | c.4052dup p.G1352Rfs*11 | Frame Shift Ins (INS) | VAF 68/250 reads (27%) | called by mutect2, pindel, varscan2
- STPG2 | c.510G>T p.M170I | Missense Mutation (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- SUPT4H1 | c.266T>C p.V89A | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- SYNE1 | c.597A>C p.E199D (on ENST00000367255 / NM_182961.4; = p.E206D on NM_033071.3) | Missense Mutation (SNP) | VAF 63/275 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- SYNJ2 | c.399G>A p.W133* | Nonsense Mutation (SNP) | VAF 104/456 reads (23%) | called by muse, varscan2
- TAB3 | c.750G>A p.W250* | Nonsense Mutation (SNP) | VAF 83/402 reads (21%) | called by muse, mutect2, varscan2
- TAF1L | c.2553del p.A852Pfs*14 | Frame Shift Del (DEL) | VAF 114/559 reads (20%) | called by mutect2, pindel, varscan2
- TANGO6 | c.1313T>C p.M438T | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TASP1 | c.1255G>T p.V419L | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TENM1 | c.6311C>T p.A2104V | Missense Mutation (SNP) | VAF 69/276 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.276); called by muse, varscan2
- TEP1 | c.4190A>T p.Q1397L | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- TEX11 | c.301G>A p.A101T (on ENST00000344304; = p.A86T on NM_031276.3) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- TFIP11 | c.670C>A p.Q224K | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- TH | c.1153G>A p.A385T (on ENST00000381178 / NM_199292.3; = p.A354T on NM_000360.4) | Missense Mutation (SNP) | VAF 63/285 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TLK1 | c.1769-2A>T p.X590_splice | Splice Site (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- TLR1 | c.184A>G p.T62A | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2
- TLX3 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 43/215 reads (20%) | called by muse, mutect2, varscan2
- TMEM131L | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2
- TMEM181 | c.101_102del p.L34Hfs*6 | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- TMEM237 | c.32A>T p.E11V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNMD | c.320del p.N107Tfs*22 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- TNXB | c.8509C>A p.L2837M (on ENST00000647633; = p.L2590M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNXB | c.6306del p.I2103Sfs*32 (on ENST00000647633; = p.I1856Sfs*32 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel
- TPM2 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.345); called by muse, mutect2
- TRAJ29 | c.2G>T p.*1= | Missense Mutation (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- TREX1 | c.350A>G p.Q117R (on ENST00000625293 / NM_033629.6; = p.Q107R on NM_007248.5) | Missense Mutation (SNP) | VAF 143/608 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TRPM4 | c.1523G>A p.R508K | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- TRPM8 | c.828G>T p.K276N | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TTI2 | c.721C>A p.L241M | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- UGT2A3 | c.967G>C p.A323P | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- UNC5D | c.2141A>G p.D714G | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- USP3 | c.92-2_92del p.X31_splice | Splice Site (DEL) | VAF 36/116 reads (31%) | called by mutect2, pindel, varscan2
- USP8 | c.2990del p.K997Rfs*2 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- UTP20 | c.4651A>C p.T1551P | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.794); called by muse, mutect2
- VIRMA | c.2163del p.F721Lfs*11 | Frame Shift Del (DEL) | VAF 18/90 reads (20%) | called by mutect2, varscan2
- VPS13B | c.4446G>T p.M1482I | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDFY3 | c.4601C>G p.S1534* | Nonsense Mutation (SNP) | VAF 33/142 reads (23%) | called by muse, mutect2, varscan2
- WDR5B | c.749G>A p.G250D | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- WDR72 | c.3298A>G p.K1100E | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- WNT10A | c.160del p.V54Cfs*9 | Frame Shift Del (DEL) | VAF 37/183 reads (20%) | called by mutect2, pindel, varscan2
- XKR5 | c.1154del p.P385Qfs*24 | Frame Shift Del (DEL) | VAF 69/367 reads (19%) | called by mutect2, pindel, varscan2
- ZBTB33 | c.578A>G p.D193G | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- ZC2HC1C | c.381del p.F128Lfs*14 | Frame Shift Del (DEL) | VAF 46/371 reads (12%) | called by mutect2, pindel, varscan2
402 further variants in this file (16 protein-altering or splice-affecting, 243 silent, 143 other) are not listed here.
